CCDI case PBBRBS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/3ed5a8f9-1978-4684-ba0f-420ffdab401d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 14.1 years (5,156 days).

Biospecimens (3 samples)
- Sample 0DEP0Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEP10: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEP1E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
